Somatic mutation profile of tumor specimen TCGA-EE-A29G-06A (aliquot TCGA-EE-A29G-06A-12D-A196-08) from TCGA case TCGA-EE-A29G, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 59.1 years (21,596 days).
Specimen TCGA-EE-A29G-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de958f1d-a3b0-4ff3-b42a-2ee437eb63af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A29G-10A (Blood Derived Normal), aliquot TCGA-EE-A29G-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c44a807f-892c-42fb-a552-23b45953c866

The open-access MAF lists 378 somatic variants for this specimen: 252 protein-altering or splice-affecting, 119 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 230, Silent 119, Nonsense Mutation 13, Splice Region 5, Splice Site 3, RNA 2, 3'UTR 2, Intron 2, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KNSTRN | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 17/75 reads (23%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as rs766760890, COSV51111003, COSV99992101; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 40/220 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABCA12 | c.5399C>T p.T1800M (on ENST00000272895 / NM_173076.3; = p.T1482M on NM_015657.3) | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs541331115, COSV55955972; called by mutect2, varscan2
- ABCB11 | c.3799G>A p.G1267S | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55591477; called by muse, mutect2, varscan2
- ABCC11 | c.3224C>T p.S1075F | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV62325826; called by muse, mutect2, varscan2
- AC097636.1 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV71309492; called by muse, mutect2
- ADAM2 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.146); catalogued as rs773158009, COSV55863118; called by muse, varscan2
- ADCY8 | c.2893G>A p.E965K | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV53926703; called by muse, mutect2, varscan2
- ADGRG4 | c.4160C>T p.P1387L | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV54957620; called by muse, mutect2, varscan2
- ADGRG5 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs865857722, COSV61082695, COSV61084540; called by muse, mutect2, varscan2
- AFF2 | c.2552G>A p.G851D | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as rs1047598664, COSV54007091; called by muse, mutect2, varscan2
- AKAP6 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55215991; called by muse, mutect2, varscan2
- ALK | c.3724G>A p.E1242K | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66563527; called by muse, mutect2, varscan2
- ANK3 | c.2739-1G>A p.X913_splice (on ENST00000280772 / NM_001320874.2; = p.X47_splice on NM_001149.3) | Splice Site (SNP) | VAF 13/31 reads (42%) | catalogued as rs1307134367, COSV55080758; called by muse, mutect2, varscan2
- ANKRD12 | c.3199G>A p.E1067K | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50847696; called by muse, mutect2
- ANKRD34B | c.1327C>T p.Q443* | Nonsense Mutation (SNP) | VAF 13/144 reads (9%) | catalogued as rs1008270083, COSV100103605; called by muse, mutect2
- APOB | c.8867C>T p.S2956F | Missense Mutation (SNP) | VAF 114/637 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as COSV51936030; called by muse, mutect2, varscan2
- APOH | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV52774958; called by muse, mutect2, varscan2
- ARL11 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as rs753334860, COSV56292190; called by mutect2, varscan2
- ASXL3 | c.4081C>T p.P1361S | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV52479082; called by muse, mutect2, varscan2
- ATP9B | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.039); catalogued as COSV56961134; called by muse, varscan2
- ATR | c.4748C>T p.S1583F | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV63387687, COSV63392180; called by muse, mutect2, varscan2
- BMPR1B | c.424A>C p.I142L | Missense Mutation (SNP) | VAF 45/307 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV52781788; called by muse, mutect2, varscan2
- BOC | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs149634735, COSV99848668; called by mutect2, varscan2
- BPTF | c.2956A>G p.K986E | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV58846482; called by muse, mutect2, varscan2
- C18orf25 | c.1122G>A p.W374* | Nonsense Mutation (SNP) | VAF 9/69 reads (13%) | catalogued as COSV56368819; called by mutect2, varscan2
- C7 | c.1417T>C p.C473R | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57480704; called by muse, mutect2
- C8orf34 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.443); catalogued as COSV61374622; called by muse, varscan2
- C9 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV54680767; called by mutect2, varscan2
- CACNA1D | c.6130C>T p.P2044S (on ENST00000350061 / NM_001128840.3; = p.P2064S on NM_000720.4) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.299); catalogued as rs753809015, COSV55444814; called by mutect2, varscan2
- CACNA1I | c.5238G>A p.M1746I | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs536287145, COSV60818358; called by muse, mutect2, varscan2
- CACNA1S | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.472); catalogued as COSV62943515; called by muse, mutect2, varscan2
- CACNG2 | c.766G>A p.G256S | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as COSV55640885; called by muse, mutect2, varscan2
- CAST | c.254C>T p.S85F (on ENST00000341926; = p.S168F on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); catalogued as COSV57789383; called by muse, mutect2, varscan2
- CC2D1B | c.2018A>G p.Q673R | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs757681288, COSV52562818; called by muse, mutect2, varscan2
- CCDC170 | c.1064T>C p.M355T | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV53346064; called by muse, mutect2, varscan2
- CD163L1 | c.4015G>A p.E1339K | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1181085302, COSV58024349; called by muse, mutect2
- CFHR5 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV56823552; called by mutect2, varscan2
- CMTM8 | c.247C>T p.L83F | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56780171; called by muse, mutect2
- CMYA5 | c.6655C>T p.P2219S | Missense Mutation (SNP) | VAF 45/256 reads (18%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV71409399; called by muse, mutect2, varscan2
- CNMD | c.716G>C p.G239A | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV65034063; called by muse, mutect2, varscan2
- CNOT4 | c.1910C>T p.S637F (on ENST00000541284 / NM_001190850.1; = p.S563F on NM_013316.4) | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV64160230; called by muse, mutect2, varscan2
- COG7 | c.1702C>T p.R568* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as rs777724580, COSV56153119; called by mutect2, varscan2
- COL1A1 | c.4328C>T p.A1443V | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1131692326, COSV56809342; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL1A2 | c.1495G>A p.G499S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51965929; called by muse, mutect2
- COL4A1 | c.3941G>A p.G1314E | Missense Mutation (SNP) | VAF 23/321 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1555301943, CM1110739, COSV65431911; ClinVar: uncertain significance; called by muse, mutect2
- COL4A6 | c.2981G>A p.R994Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.095); catalogued as rs772125106, COSV57877703; called by mutect2, varscan2
- COL6A6 | c.6382G>A p.E2128K | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62028621; called by muse, mutect2, varscan2
- CPD | c.2771C>T p.S924L | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.108); catalogued as COSV56716240; called by muse, mutect2, varscan2
- CRB2 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV63505460; called by mutect2, varscan2
- CSMD2 | c.8192A>G p.N2731S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.411); catalogued as COSV53960675; called by muse, mutect2, varscan2
- CSMD3 | c.6952G>A p.G2318R (on ENST00000297405 / NM_001363185.1; = p.G2214R on NM_052900.3) | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1484431339, COSV52091825, COSV52314785; called by muse, mutect2, varscan2
- CYFIP2 | c.958A>T p.K320* | Nonsense Mutation (SNP) | VAF 33/263 reads (13%) | catalogued as rs3207362, COSV59050344; called by muse, mutect2, varscan2
- CYFIP2 | c.2985G>A p.G995= (on ENST00000616178 / NM_001291722.2; = p.G970= on NM_014376.4) | Splice Region (SNP) | VAF 22/150 reads (15%) | catalogued as COSV59050364; called by muse, varscan2
- CYP4F2 | c.648G>A p.E216= | Splice Region (SNP) | VAF 28/183 reads (15%) | catalogued as COSV50000519; called by muse, mutect2, varscan2
- DDB1 | c.1838A>G p.Y613C | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs1363549372, COSV57105683; called by muse, mutect2, varscan2
- DENND1B | c.2171C>T p.S724L | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.236); catalogued as rs1213502120, COSV54147668; called by mutect2, varscan2
- DENND6A | c.1354-2A>G p.X452_splice | Splice Site (SNP) | VAF 9/107 reads (8%) | catalogued as COSV60770128; called by muse, mutect2
- DKK2 | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs1325337791, COSV53394608; called by mutect2, varscan2
- DLGAP2 | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs1363798583, COSV70096510; called by muse, mutect2, varscan2
- DMBT1 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57561120; called by muse, mutect2, varscan2
- DMBT1 | c.7205C>T p.P2402L (on ENST00000338354 / NM_001377530.1; = p.P1645L on NM_004406.3) | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57561141; called by muse, mutect2, varscan2
- DNAH3 | c.8705C>T p.A2902V | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779948624, COSV54550536; called by muse, mutect2, varscan2
- DNAH5 | c.6446T>C p.V2149A | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); catalogued as COSV54250989, COSV99444270; called by muse, mutect2, varscan2
- DNAH9 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.082); catalogued as COSV52376139; called by mutect2, varscan2
- DNAJC2 | c.1571A>T p.K524M | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50788015; called by mutect2, varscan2
- DNM1L | c.590T>C p.L197P | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56777833; called by muse, mutect2, varscan2
- DPYD | c.1259A>T p.N420I | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV64614132; called by muse, mutect2, varscan2
- DSCAM | c.5468T>C p.M1823T | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV68035868; called by muse, mutect2
- DSCAM | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.45); catalogued as rs375818015; called by mutect2, varscan2
- DSPP | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as COSV56816279; called by muse, mutect2, varscan2
- ECM2 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV60742895; called by muse, mutect2
- EFCAB12 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV58178689; called by muse, mutect2, varscan2
- EFEMP1 | c.1265C>T p.T422I | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV62617862; called by muse, mutect2, varscan2
- EPHB1 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 30/261 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs1330628001, COSV67671236; called by mutect2, varscan2
- ETV1 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.07); catalogued as COSV54151214; called by muse, mutect2, varscan2
- FAM118A | c.152C>G p.S51W | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53419478; called by muse, mutect2, varscan2
- FAM135B | c.3169T>A p.F1057I | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV99426390; called by muse, mutect2, varscan2
- FAM83A | c.749G>A p.R250K | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.908); catalogued as COSV52688036; called by muse, mutect2, varscan2
- FAM83D | c.1460T>C p.V487A | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.057); catalogued as COSV54157263; called by muse, mutect2, varscan2
- FCGR3A | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 30/291 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777467556, COSV63460569; called by muse, mutect2
- FETUB | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 18/217 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV54007181; called by muse, mutect2
- FGFR1 | c.1694C>T p.S565F (on ENST00000447712 / NM_023110.3; = p.S563F on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs768223019, COSV58344221; called by mutect2, varscan2
- FGFR4 | c.2266G>A p.D756N | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs192201146; called by mutect2, varscan2
- FHL5 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as rs754828656, COSV58738983, COSV58740066; called by muse, mutect2, varscan2
- FLT3 | c.1850G>A p.G617E | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54049176, COSV54063534; called by muse, mutect2, varscan2
- FSTL5 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs779449215, COSV60198887; called by mutect2, varscan2
- GABRG1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT tolerated (1); PolyPhen possibly damaging (0.689); catalogued as COSV54951561, COSV54962652; called by muse, mutect2, varscan2
- GALNT14 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.313); catalogued as rs1048696828, COSV61111062; called by muse, mutect2, varscan2
- GCK | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 36/337 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61755512; called by muse, varscan2
- GDI1 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 72/219 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV50133040; called by muse, mutect2, varscan2
- GIMAP1 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 25/354 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs867001533, COSV56188051; called by muse, mutect2
- GIMAP7 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV57960552; called by muse, mutect2, varscan2
- GLIPR1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs574219796, COSV56990729; called by mutect2, varscan2
- H2BW1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as rs1372913053, COSV54220215, COSV99475140; called by muse, mutect2, varscan2
- HADHB | c.1219A>G p.T407A | Missense Mutation (SNP) | VAF 25/271 reads (9%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV58548626; called by muse, mutect2
- HAPLN1 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.208); catalogued as COSV57151967, COSV99164607; called by muse, mutect2, varscan2
- HHAT | c.1342G>C p.G448R | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV54809572; called by muse, mutect2
- HHIP | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs768159746, COSV56838147, COSV56844040; called by muse, mutect2, varscan2
- HHLA2 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as COSV63319912; called by muse, varscan2
- IFT122 | c.943G>A p.G315R (on ENST00000348417 / NM_052989.3; = p.G256R on NM_018262.4) | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56207989; called by muse, mutect2, varscan2
- IGSF21 | c.1099C>T p.Q367* | Nonsense Mutation (SNP) | VAF 12/105 reads (11%) | catalogued as rs867147194, COSV52137325; called by mutect2, varscan2
- IQGAP2 | c.448C>T p.H150Y | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1451888454, COSV57182384; called by mutect2, varscan2
- ITGA8 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.367); catalogued as rs867373846, COSV65226094; called by muse, mutect2, varscan2
- KANK4 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.703); catalogued as COSV62989273; called by mutect2, varscan2
- KAT8 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 56/303 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.914); catalogued as COSV54898850; called by muse, mutect2, varscan2
- KCNA10 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0.018); catalogued as COSV63905305; called by muse, mutect2, varscan2
- KCNG4 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV57585892; called by muse, mutect2, varscan2
- KIAA0408 | c.1978C>T p.R660C | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs201926296, COSV64116350; called by mutect2, varscan2
- KIAA1109 | c.7676C>T p.S2559F | Missense Mutation (SNP) | VAF 49/372 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV52661983; called by muse, mutect2, varscan2
- KIAA1217 | c.3607C>T p.Q1203* | Nonsense Mutation (SNP) | VAF 12/69 reads (17%) | catalogued as COSV56823588; called by muse, mutect2, varscan2
- KIFC2 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1019011084, COSV56763415; called by muse, mutect2, varscan2
- KIR3DL3 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 39/353 reads (11%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.867); catalogued as rs1169091421, COSV52551056; called by muse, mutect2, varscan2
- KLC2 | c.753G>A p.R251= | Splice Region (SNP) | VAF 8/50 reads (16%) | catalogued as COSV57584292; called by muse, mutect2
- KSR2 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV60370092; called by muse, mutect2, varscan2
- LCP2 | c.1395C>G p.Y465* | Nonsense Mutation (SNP) | VAF 11/89 reads (12%) | catalogued as COSV50465219; called by muse, mutect2, varscan2
- LEPR | c.2734C>T p.L912F | Missense Mutation (SNP) | VAF 53/307 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62747513, COSV62750356; called by muse, mutect2, varscan2
- LILRB3 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV54427518; called by muse, mutect2, varscan2
- LRP2 | c.13415A>G p.E4472G | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.576); catalogued as COSV55573590; called by muse, mutect2, varscan2
- LRP2 | c.7268C>T p.S2423F | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as rs866984399, COSV55573599; called by muse, mutect2, varscan2
- LRTM1 | c.807G>C p.L269F | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.086); catalogued as COSV55580926; called by muse, mutect2, varscan2
- MAGEA1 | c.559C>T p.Q187* | Nonsense Mutation (SNP) | VAF 24/78 reads (31%) | catalogued as COSV63118959, COSV63119251; called by mutect2, varscan2
- MAGEC2 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV56000605; called by muse, mutect2, varscan2
- MAP7 | c.635G>A p.R212K | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as COSV63422985; called by muse, mutect2, varscan2
- MAPKAPK3 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63598523; called by muse, mutect2, varscan2
- MAST4 | c.642G>A p.L214= | Splice Region (SNP) | VAF 7/27 reads (26%) | catalogued as COSV68247141; called by muse, mutect2, varscan2
- MEGF8 | c.8179C>T p.R2727C (on ENST00000251268 / NM_001271938.2; = p.R2660C on NM_001410.3) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs773723714, COSV52079585; called by muse, mutect2, varscan2
- METTL16 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.033); catalogued as rs765012986, COSV54016344; called by muse, mutect2, varscan2
- MMP3 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100242960; called by muse, mutect2, varscan2
- MOV10 | c.353T>C p.L118P | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV62492675; called by muse, mutect2, varscan2
- MSH4 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.406); catalogued as COSV99592282; called by muse, mutect2, varscan2
- MUSK | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.054); catalogued as COSV51894259; called by muse, varscan2
- MYO18B | c.6471G>C p.R2157S | Missense Mutation (SNP) | VAF 42/252 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV59148138, COSV59148223; called by muse, mutect2, varscan2
- NKG7 | c.169G>C p.V57L | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV52468166; called by muse, mutect2, varscan2
- NYNRIN | c.4169C>T p.P1390L | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV66844948; called by muse, mutect2, varscan2
- OPCML | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs898932537, COSV59449572; called by muse, mutect2, varscan2
- OR10P1 | c.186C>G p.F62L | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV59008432; called by muse, mutect2, varscan2
- OR2G3 | c.329C>T p.T110I | Missense Mutation (SNP) | VAF 58/320 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV60683113; called by muse, mutect2, varscan2
- OR2T10 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.119); catalogued as COSV57898349; called by mutect2, varscan2
- OR2V2 | c.527A>G p.N176S | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as rs1374453816, COSV60316441; called by muse, mutect2, varscan2
- OR2W1 | c.312C>G p.Y104* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as COSV65851914; called by muse, mutect2, varscan2
- OR5T1 | c.758G>T p.C253F | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57302918; called by muse, mutect2, varscan2
- OR8H1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as rs199982658, COSV57293040; called by muse, varscan2
- OSBPL3 | c.1168C>A p.Q390K | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.214); catalogued as COSV57662360; called by muse, mutect2, varscan2
- OTUB1 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.895); catalogued as rs1438775569, COSV55367269; called by muse, varscan2
- PAG1 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55061899; called by mutect2, varscan2
- PAPOLG | c.1664T>A p.V555E | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV53185659; called by muse, mutect2, varscan2
- PCDH18 | c.2114C>T p.S705F | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV61266449; called by muse, mutect2, varscan2
- PCDHB14 | c.2191C>T p.P731S | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.011); catalogued as rs782018469, COSV53391261, COSV99506226; called by muse, mutect2, varscan2
- PCYT1B | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.136); catalogued as COSV63263950; called by muse, mutect2, varscan2
- PDE4B | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as COSV58495079; called by muse, mutect2, varscan2
- PDGFRL | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.122); catalogued as rs770581489, COSV52411065; called by muse, mutect2, varscan2
- PGLYRP2 | c.844C>T p.L282F | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52991637; called by muse, mutect2
- PHEX | c.607T>C p.F203L | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65079015; called by muse, mutect2, varscan2
- PKD2L1 | c.1151G>A p.S384N | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as COSV58398789; called by muse, mutect2, varscan2
- PLCE1 | c.3767C>T p.T1256I | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); catalogued as COSV53371570; called by muse, mutect2, varscan2
- PLCH2 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV53949429; called by muse, varscan2
- PLEKHA4 | c.1720C>T p.P574S | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV54366123; called by muse, mutect2
- PLEKHG7 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV60822786; called by mutect2, varscan2
- POF1B | c.1253G>A p.R418K | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV53140132, COSV99425799; called by muse, mutect2, varscan2
- POP1 | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.174); catalogued as COSV62894134; called by muse, mutect2, varscan2
- PPIC | c.172C>T p.L58F | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60575295; called by muse, mutect2, varscan2
- PPP1R36 | c.891-1G>A p.X297_splice | Splice Site (SNP) | VAF 7/99 reads (7%) | catalogued as COSV53903904; called by muse, mutect2
- PRB1 | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV53702817, COSV53706584; called by muse, mutect2
- PRB2 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 36/310 reads (12%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as rs772656544, COSV66983894; called by muse, varscan2
- PREX2 | c.2815C>T p.H939Y | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV55798020; called by muse, mutect2
- PREX2 | c.4219C>T p.L1407F | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55761761, COSV55769145, COSV99910499; called by muse, mutect2, varscan2
- PRSS58 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.091); catalogued as COSV73488856; called by muse, varscan2
- PTPN13 | c.3380C>T p.A1127V (on ENST00000411767 / NM_080683.3; = p.A1108V on NM_006264.3) | Missense Mutation (SNP) | VAF 58/260 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.078); catalogued as COSV57417191; called by muse, mutect2, varscan2
- PWWP3B | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61801688; called by muse, mutect2, varscan2
- RAD54L2 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs952375132, COSV56579615; called by mutect2, varscan2
- RALGPS2 | c.509T>C p.F170S | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61339834; called by muse, mutect2, varscan2
- RALYL | c.189G>A p.M63I | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs1194350025, COSV101569682; called by mutect2, varscan2
- RASSF2 | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 36/316 reads (11%) | catalogued as COSV65082884, COSV65083210; called by mutect2, varscan2
- RBM46 | c.1466G>A p.G489E | Missense Mutation (SNP) | VAF 42/330 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV55981957; called by muse, mutect2, varscan2
- RERE | c.1745C>G p.S582W | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV61950605; called by muse, mutect2, varscan2
- RND1 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1164848675, COSV59045000, COSV59045917; called by mutect2, varscan2
- RNF123 | c.3440C>T p.P1147L | Missense Mutation (SNP) | VAF 31/283 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57540123; called by muse, mutect2, varscan2
- RUNX1T1 | c.1072G>A p.D358N (on ENST00000265814 / NM_001198628.1; = p.D331N on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.168); catalogued as COSV56158111, COSV56162539; called by muse, mutect2, varscan2
- RYR2 | c.2171C>T p.S724F | Missense Mutation (SNP) | VAF 29/224 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63712688; called by muse, mutect2, varscan2
- SALL1 | c.2965C>T p.L989F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV51764421; called by muse, mutect2, varscan2
- SASH1 | c.1759A>G p.S587G | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV66565811; called by muse, varscan2
- SCN5A | c.3232G>A p.E1078K (on ENST00000333535 / NM_198056.3; = p.E1077K on NM_000335.5) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.973); catalogued as COSV61138938; called by muse, mutect2, varscan2
- SCN5A | c.1721G>A p.G574E | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.305); catalogued as rs1559771438, CD100781, COSV61140303; called by muse, mutect2, varscan2
- SCP2D1 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV53858735; called by muse, mutect2, varscan2
- SDR16C5 | c.917A>C p.K306T | Missense Mutation (SNP) | VAF 24/335 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV100374101; called by muse, mutect2
- SERPINH1 | c.988A>G p.I330V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63998540; called by muse, mutect2, varscan2
- SETD2 | c.5189C>T p.S1730F | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV57451455; called by muse, mutect2, varscan2
- SETD5 | c.949T>C p.F317L | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56717265; called by muse, mutect2, varscan2
- SEZ6L | c.431G>A p.R144K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.039); catalogued as COSV50686136; called by muse, mutect2
- SGMS1 | c.390G>A p.M130I | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as COSV62373072; called by muse, mutect2, varscan2
- SH3RF2 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV63040834; called by muse, mutect2, varscan2
- SHCBP1L | c.1585C>T p.Q529* | Nonsense Mutation (SNP) | VAF 14/83 reads (17%) | catalogued as COSV62357140; called by muse, mutect2, varscan2
- SHE | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV59073204; called by muse, mutect2, varscan2
- SHROOM2 | c.2425C>T p.P809S | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV66606331; called by muse, mutect2, varscan2
- SLC10A3 | c.937C>T p.H313Y | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54837460; called by muse, mutect2, varscan2
- SLC39A6 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs760828526, COSV52371350; called by muse, mutect2, varscan2
- SLC44A3 | c.563C>T p.S188F (on ENST00000271227 / NM_001114106.3; = p.S140F on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV54733886; called by muse, mutect2, varscan2
- SLC6A13 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58260264; called by muse, mutect2, varscan2
- SLC6A14 | c.564G>A p.M188I | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV64148668; called by mutect2, varscan2
- SLC6A14 | c.1607T>A p.L536H | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64148674; called by mutect2, varscan2
- SLFN13 | c.1267C>G p.L423V | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs1215138700, COSV53195593; called by muse, mutect2, varscan2
- SLITRK1 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.138); catalogued as COSV65674545; called by muse, varscan2
- SPP1 | c.255G>A p.M85I (on ENST00000395080 / NM_001040058.2; = p.M71I on NM_000582.2) | Missense Mutation (SNP) | VAF 105/317 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.059); catalogued as COSV52952766; called by muse, mutect2, varscan2
- ST18 | c.1961C>T p.A654V | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as rs769020500, COSV52508950; called by mutect2, varscan2
- STAG1 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52623662; called by muse, mutect2
- STARD4 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs369793461; called by mutect2, varscan2
- TARBP1 | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV50205959; called by muse, mutect2, varscan2
- TAS2R41 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV68765865; called by muse, mutect2, varscan2
- TBC1D21 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.013); catalogued as COSV55996759; called by muse, mutect2, varscan2
- TBC1D9B | c.1106C>T p.T369I | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.703); catalogued as COSV100783625; called by muse, mutect2
- TBRG4 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV51833457; called by muse, mutect2, varscan2
- TCHHL1 | c.2131G>A p.G711R | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.083); catalogued as COSV64286424; called by muse, mutect2, varscan2
- TENM2 | c.4879G>A p.E1627K (on ENST00000518659 / NM_001122679.2; = p.E1388K on NM_001080428.3) | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.057); catalogued as COSV69140813; called by mutect2, varscan2
- TEX44 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV58354587; called by muse, mutect2, varscan2
- TEX55 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV55212892; called by mutect2, varscan2
- TFDP1 | c.347T>C p.L116P | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64742666; called by muse, mutect2, varscan2
- TG | c.1882G>A p.D628N | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV55093673; called by muse, mutect2, varscan2
- TMC2 | c.555G>A p.R185= | Splice Region (SNP) | VAF 8/68 reads (12%) | catalogued as COSV62658153; called by muse, varscan2
- TMC2 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1461476053, COSV62652818; called by mutect2, varscan2
- TMEM186 | c.74G>C p.W25S | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.332); catalogued as COSV51634378; called by muse, mutect2
- TMEM219 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54244741; called by muse, mutect2, varscan2
- TNFRSF8 | c.111T>G p.Y37* | Nonsense Mutation (SNP) | VAF 22/121 reads (18%) | catalogued as COSV55800688; called by muse, mutect2, varscan2
- TNKS2 | c.525A>T p.E175D | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.047); catalogued as COSV65416955; called by muse, mutect2, varscan2
- TTC26 | c.989G>A p.G330D | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58274322; called by muse, mutect2, varscan2
- TTC30B | c.794G>A p.R265K | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746732905, COSV68809263; called by muse, mutect2, varscan2
- TTN | c.77866G>A p.D25956N (on ENST00000591111; = p.D18532N on NM_003319.4) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | PolyPhen probably damaging (0.998); catalogued as COSV60339436; called by mutect2, varscan2
- TTN | c.15688G>A p.E5230K (on ENST00000591111; = p.E4303K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/191 reads (18%) | PolyPhen benign (0.018); catalogued as rs766334270, COSV59903845; called by muse, mutect2, varscan2
- UBR4 | c.1219C>T p.Q407* | Nonsense Mutation (SNP) | VAF 24/130 reads (18%) | catalogued as COSV64398264; called by muse, mutect2, varscan2
- UGT2B28 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100158759, COSV59430976; called by muse, mutect2, varscan2
- USP2 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as rs375539156; called by mutect2, varscan2
- USP29 | c.1048T>A p.L350I | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV54146525; called by muse, mutect2, varscan2
- USP33 | c.1310C>T p.S437L | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs1314460356, COSV62468590; called by mutect2, varscan2
- VWA3A | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV55389535, COSV55394512; called by muse, mutect2, varscan2
- WDFY3 | c.5471C>T p.S1824F | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55713517; called by muse, mutect2, varscan2
- WDFY3 | c.1943T>C p.V648A | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as COSV55713528; called by muse, mutect2, varscan2
- WDR54 | c.268T>C p.S90P | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51966187; called by muse, mutect2, varscan2
- WWC3 | c.1163C>T p.S388L | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs1425513708, COSV66507317; called by mutect2, varscan2
- ZFHX4 | c.6490G>A p.E2164K | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as COSV99261826; called by muse, mutect2, varscan2
- ZIM3 | c.1327G>A p.G443R | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV54146533, COSV54146572; called by muse, mutect2, varscan2
- ZNF180 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV55424281; called by mutect2, varscan2
- ZNF208 | c.872G>A p.G291D | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as COSV68109219; called by muse, mutect2, varscan2
- ZNF514 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs367936062; called by muse, mutect2, varscan2
- ZNF570 | c.1222C>T p.H408Y | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57580806; called by mutect2, varscan2
- ZNF638 | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.82); catalogued as COSV52496706; called by muse, mutect2, varscan2
- ZNF683 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.166); catalogued as COSV62875846; called by muse, mutect2
- CEL | c.202C>T p.P68S (on ENST00000673714; = p.P65S on NM_001807.6) | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CYFIP1 | c.659T>C p.I220T | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- KIR2DS4 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 30/263 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- PRAMEF18 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 60/863 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2
- TAOK2 | c.369del p.Q124Rfs*3 | Frame Shift Del (DEL) | VAF 29/154 reads (19%) | called by mutect2, pindel, varscan2
- XKR3 | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by mutect2, varscan2
- ABCD2 | c.477C>T p.F159= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV58053430; called by mutect2, varscan2
- AHDC1 | c.2395C>A p.R799= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as rs746453956, COSV55942312; called by muse, mutect2, varscan2
- ANAPC1 | c.2781T>G p.A927= | Silent (SNP) | VAF 25/316 reads (8%) | catalogued as COSV61979449; called by muse, mutect2
- ANAPC1 | c.1545A>C p.P515= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV61979457; called by muse, mutect2, varscan2
- APC | c.8367C>T p.S2789= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as rs786201474, COSV57380917; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP10A | c.3117C>T p.I1039= | Silent (SNP) | VAF 62/308 reads (20%) | catalogued as rs753965628, COSV63523984; called by muse, mutect2, varscan2
- ATP10D | c.1653A>G p.P551= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as rs776169220, COSV56713084; called by muse, mutect2, varscan2
- BSN | c.10533G>A p.L3511= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV56527103; called by muse, mutect2, varscan2
- C2CD6 | c.381A>G p.Q127= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV53800489; called by muse, mutect2, varscan2
- CACNA1E | c.4230C>T p.F1410= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as COSV62396516; called by muse, mutect2, varscan2
- CAD | c.3672C>T p.P1224= | Silent (SNP) | VAF 34/187 reads (18%) | catalogued as COSV53031697; called by muse, mutect2, varscan2
- CASR | c.258C>T p.A86= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV56141366; called by muse, mutect2, varscan2
- CCDC127 | c.276C>T p.L92= | Silent (SNP) | VAF 38/112 reads (34%) | catalogued as rs751733851, COSV57258063; called by mutect2, varscan2
- CCDC88C | c.4095G>A p.E1365= | Silent (SNP) | VAF 14/225 reads (6%) | catalogued as COSV66241554; called by muse, mutect2
- CD300C | c.513C>T p.P171= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV100423310; called by muse, mutect2, varscan2
- CDH10 | c.699C>T p.Y233= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV52597171; called by muse, mutect2, varscan2
- CDH8 | c.732C>T p.I244= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as COSV54899209; called by muse, mutect2, varscan2
- CEP170 | c.288C>T p.F96= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs1172894654, COSV60514610; called by mutect2, varscan2
- CFAP61 | c.1137C>T p.P379= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as COSV55647110; called by muse, mutect2, varscan2
- CHRM2 | c.516G>A p.E172= | Silent (SNP) | VAF 16/168 reads (10%) | catalogued as COSV57765010, COSV57773638, COSV57786807; called by muse, varscan2
- CNGB3 | c.873G>A p.R291= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as COSV60687447; called by muse, mutect2, varscan2
- COL4A1 | c.2979T>G p.G993= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV65431922; called by muse, mutect2, varscan2
- COL7A1 | c.5253G>A p.R1751= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV60402843; called by muse, mutect2, varscan2
- CRISPLD2 | c.1386G>T p.V462= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV52283057; called by mutect2, varscan2
- DAB1 | c.633T>A p.R211= | Silent (SNP) | VAF 28/151 reads (19%) | catalogued as COSV59736882; called by muse, mutect2, varscan2
- DAB2 | c.702C>T p.I234= | Silent (SNP) | VAF 24/133 reads (18%) | catalogued as COSV100298113, COSV57918918; called by muse, mutect2, varscan2
- DDX17 | c.1110C>T p.F370= | Silent (SNP) | VAF 32/243 reads (13%) | catalogued as COSV53256427; called by muse, mutect2, varscan2
- DNAH5 | c.4851C>T p.N1617= | Silent (SNP) | VAF 38/187 reads (20%) | catalogued as COSV54250999; called by muse, mutect2, varscan2
- DNAH8 | c.12127T>C p.L4043= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV100545056, COSV59479395; called by muse, mutect2, varscan2
- DNAJB2 | c.309C>T p.F103= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV60677919; called by muse, varscan2
- DOCK9 | c.4221T>C p.L1407= (on ENST00000376460 / NM_001366676.2; = p.L1408= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs1423917738, COSV59642995; called by muse, mutect2, varscan2
- DSCAM | c.1371G>A p.Q457= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV68020323, COSV68028921; called by muse, mutect2, varscan2
- DYSF | c.6132G>A p.R2044= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV50574953; called by muse, mutect2, varscan2
- ENPEP | c.366C>T p.S122= | Silent (SNP) | VAF 13/197 reads (7%) | catalogued as COSV54457257; called by muse, mutect2
- ERAP2 | c.2731T>C p.L911= | Silent (SNP) | VAF 20/199 reads (10%) | catalogued as COSV65941357; called by muse, mutect2
- F3 | c.327C>T p.S109= | Silent (SNP) | VAF 37/229 reads (16%) | catalogued as COSV61845576; called by muse, mutect2, varscan2
- FAM24B | c.12C>T p.I4= | Silent (SNP) | VAF 25/117 reads (21%) | catalogued as rs758221112, COSV59028101; called by mutect2, varscan2
- FLNB | c.2220C>T p.S740= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as COSV55894860; called by muse, mutect2
- FZD6 | c.822C>T p.V274= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV62472655; called by muse, mutect2, varscan2
- GADL1 | c.1146C>T p.I382= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV56985638; called by muse, mutect2, varscan2
- GCSAM | c.324G>A p.E108= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as rs769756753, COSV100453216, COSV58264551; called by muse, mutect2, varscan2
- GRIA1 | c.471C>T p.V157= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV53623964; called by muse, mutect2, varscan2
- GRM3 | c.2083C>T p.L695= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV64479471; called by muse, mutect2, varscan2
- GRM7 | c.2580G>A p.K860= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV63170430; called by muse, mutect2, varscan2
- GSTM2 | c.627C>T p.F209= | Silent (SNP) | VAF 40/204 reads (20%) | catalogued as COSV53984003; called by mutect2, varscan2
- ICAM3 | c.204C>T p.S68= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV50330086, COSV99349230; called by muse, mutect2, varscan2
- IGF2 | c.297C>T p.F99= (on ENST00000434045 / NM_001127598.3; = p.F43= on NM_000612.6) | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs140032633; ClinVar: likely benign; called by mutect2, varscan2
- IL17RC | c.1251C>T p.S417= (on ENST00000295981 / NM_153461.4; = p.S331= on NM_032732.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV55974962; called by muse, mutect2, varscan2
- KCNH1 | c.705C>T p.V235= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV55103121; called by muse, mutect2, varscan2
- KCNH5 | c.1980C>T p.F660= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as COSV59777409; called by muse, mutect2
- KIF21B | c.138G>A p.K46= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV59766256; called by muse, mutect2, varscan2
- KIFC2 | c.1356C>T p.F452= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as rs141511686; called by muse, mutect2, varscan2
- KRT73 | c.1527G>A p.G509= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV59839584, COSV99988845; called by muse, mutect2
- LALBA | c.255C>T p.V85= | Silent (SNP) | VAF 12/131 reads (9%) | catalogued as COSV56396510; called by muse, mutect2, varscan2
- LRRC49 | c.1419C>T p.F473= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV53015384; called by muse, mutect2, varscan2
- MAGI1 | c.2526C>T p.I842= (on ENST00000402939 / NM_001033057.2; = p.I870= on NM_004742.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as rs1348098781, COSV58340296, COSV58344143; called by mutect2, varscan2
- MAPK3 | c.555C>T p.F185= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs143182888; called by mutect2, varscan2
- MARF1 | c.3675C>T p.I1225= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as rs368752613; called by muse, mutect2, varscan2
- MEGF8 | c.1734T>C p.S578= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV52101176; called by muse, mutect2, varscan2
- MGAT3 | c.144C>T p.S48= | Silent (SNP) | VAF 42/280 reads (15%) | catalogued as rs777743562, COSV57868370; called by muse, mutect2, varscan2
- MICAL2 | c.3207G>A p.R1069= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as rs377311550; called by muse, varscan2
- MRC2 | c.280C>T p.L94= | Silent (SNP) | VAF 7/93 reads (8%) | catalogued as COSV57644449; called by muse, mutect2
- MRGPRX1 | c.711C>T p.F237= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV57106307; called by muse, mutect2, varscan2
- MUC16 | c.40509G>A p.K13503= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV66696344; called by muse, mutect2, varscan2
- MUC16 | c.1086G>A p.E362= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV67492390; called by muse, mutect2, varscan2
- MUCL1 | c.249C>T p.L83= | Silent (SNP) | VAF 24/185 reads (13%) | catalogued as COSV58193778; called by muse, mutect2, varscan2
- N6AMT1 | c.213T>C p.A71= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100375065, COSV58135805; called by muse, mutect2, varscan2
- NAALAD2 | c.1479A>C p.S493= | Silent (SNP) | VAF 28/209 reads (13%) | catalogued as COSV58966014; called by muse, mutect2, varscan2
- NMUR2 | c.138C>T p.L46= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV54922541; called by muse, mutect2, varscan2
- NPAP1 | c.1809C>T p.S603= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV61510925; called by muse, mutect2, varscan2
- NRG3 | c.1551G>A p.R517= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs761374063, COSV64583486; called by muse, mutect2, varscan2
- OR10R2 | c.825T>G p.A275= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV63769527; called by muse, mutect2
- OR13C8 | c.39C>T p.F13= | Silent (SNP) | VAF 14/105 reads (13%) | catalogued as rs758343445, COSV58610595; called by muse, mutect2, varscan2
- OR13C8 | c.252C>T p.S84= | Silent (SNP) | VAF 25/280 reads (9%) | catalogued as rs150711746, COSV58612403; called by muse, mutect2
- OR5D13 | c.672C>T p.F224= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV62335329; called by mutect2, varscan2
- OR5L1 | c.339C>T p.F113= | Silent (SNP) | VAF 24/169 reads (14%) | catalogued as COSV61735368; called by muse, mutect2, varscan2
- PAGE2B | c.159G>A p.G53= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs1025370650, COSV66611640; called by muse, mutect2, varscan2
- PCDH15 | c.4992T>C p.F1664= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV57391507; called by muse, mutect2, varscan2
- PCDHB4 | c.2340G>A p.R780= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as rs144682616, COSV52026874; called by muse, mutect2
- PEG3 | c.3759G>A p.L1253= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV55647095; called by mutect2, varscan2
- PHF2 | c.2673C>T p.S891= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as COSV63683809; called by muse, mutect2, varscan2
- PKHD1L1 | c.10038C>T p.F3346= | Silent (SNP) | VAF 12/117 reads (10%) | called by muse, mutect2, varscan2
- PPIL1 | c.489C>T p.Y163= | Silent (SNP) | VAF 26/119 reads (22%) | catalogued as rs774621142, COSV65473060; called by muse, mutect2, varscan2
- PRAG1 | c.2445C>T p.L815= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as rs1299415303, COSV100422646, COSV58168208; called by muse, mutect2, varscan2
- PROKR2 | c.615G>A p.K205= | Silent (SNP) | VAF 19/142 reads (13%) | catalogued as COSV54089194, COSV99450353; called by muse, mutect2, varscan2
- PRRC2A | c.5439C>T p.S1813= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV52994879; called by muse, mutect2, varscan2
- PSD2 | c.1485C>T p.I495= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as rs1401367400, COSV51210350; called by muse, mutect2, varscan2
- RAB34 | c.418C>T p.L140= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as COSV56388706, COSV99040004; called by muse, mutect2
- RBM12 | c.411C>T p.T137= | Silent (SNP) | VAF 24/162 reads (15%) | catalogued as rs778235130, COSV58294980; called by muse, mutect2, varscan2
- RHBDF2 | c.1986C>T p.F662= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV51686289; called by muse, varscan2
- RTL3 | c.234G>A p.K78= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV58183644, COSV58184010; called by muse, mutect2
- RWDD3 | c.42G>A p.A14= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV55722994; called by mutect2, varscan2
- RYR2 | c.6582C>T p.A2194= | Silent (SNP) | VAF 48/357 reads (13%) | catalogued as COSV63712693; called by muse, mutect2, varscan2
- SBK1 | c.282C>T p.F94= | Silent (SNP) | VAF 17/173 reads (10%) | catalogued as COSV59398285; called by muse, mutect2
- SCN5A | c.2274G>A p.G758= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as CD100785, COSV61140293; called by muse, mutect2, varscan2
- SLC22A15 | c.931C>T p.L311= | Silent (SNP) | VAF 8/148 reads (5%) | catalogued as COSV65679043; called by muse, mutect2
- SLC4A8 | c.2823C>T p.F941= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as COSV60654447, COSV60658125; called by muse, mutect2, varscan2
- SLC6A15 | c.1374C>T p.F458= | Silent (SNP) | VAF 23/133 reads (17%) | catalogued as COSV57029555; called by muse, mutect2, varscan2
- SLC6A20 | c.1755G>A p.R585= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV62072762; called by muse, mutect2, varscan2
- SLC7A3 | c.498C>T p.F166= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs141540446, COSV53229242; called by muse, mutect2, varscan2
- SLC7A9 | c.1101C>T p.I367= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as COSV50093904; called by muse, mutect2, varscan2
- SPRR3 | c.45G>A p.Q15= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV54880410, COSV54881345; called by muse, mutect2, varscan2
- STRC | c.5148C>T p.V1716= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV55853659; called by mutect2, varscan2
- SWT1 | c.720C>T p.S240= | Silent (SNP) | VAF 28/194 reads (14%) | catalogued as rs1414434290, COSV62258989; called by muse, mutect2, varscan2
- SYNJ2 | c.2652C>T p.F884= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV62900086; called by muse, mutect2, varscan2
- SYT9 | c.1353G>A p.E451= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs1382948787, COSV59625081; called by muse, mutect2, varscan2
- TIAM2 | c.447C>T p.S149= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs1411920040, COSV59704104; called by muse, varscan2
- TMEM192 | c.318C>T p.L106= | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as rs774346631, COSV60586243; called by muse, mutect2, varscan2
- TMEM94 | c.528C>T p.N176= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV58599826; called by muse, mutect2, varscan2
- TRPM3 | c.1413C>T p.I471= (on ENST00000357533 / NM_001366142.2; = p.I316= on NM_020952.6) | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs763650106, COSV62594553; called by mutect2, varscan2
- TTN | c.22977C>T p.V7659= (on ENST00000591111; = p.V6732= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/299 reads (20%) | catalogued as COSV60339589; called by muse, mutect2, varscan2
- UGT2B15 | c.75G>A p.K25= | Silent (SNP) | VAF 140/579 reads (24%) | catalogued as rs1394462183, COSV57735844; called by muse, mutect2, varscan2
- ULK1 | c.849G>A p.S283= | Silent (SNP) | VAF 21/167 reads (13%) | catalogued as rs548811285, COSV58856754, COSV58859859; called by muse, mutect2, varscan2
- VIRMA | c.4749C>G p.T1583= | Silent (SNP) | VAF 13/163 reads (8%) | catalogued as COSV52591147; called by muse, mutect2
- ZCCHC12 | c.849G>A p.Q283= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV59571700; called by muse, mutect2, varscan2
- ZFHX4 | c.633C>T p.F211= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV51495473; called by muse, mutect2, varscan2
- ZFPM2 | c.889C>T p.L297= | Silent (SNP) | VAF 23/177 reads (13%) | catalogued as COSV65873101, COSV65874647; called by muse, mutect2, varscan2
- ZNF510 | c.396C>T p.I132= | Silent (SNP) | VAF 26/161 reads (16%) | catalogued as COSV56299030; called by muse, mutect2, varscan2
- ZNF792 | c.1728C>T p.T576= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV101289672, COSV68694388; called by muse, mutect2
- AL353804.7 | chrX:73845913 G>A | 5'Flank (SNP) | VAF 30/97 reads (31%) | called by mutect2, varscan2
- ARPP19P2 | n.109C>T | RNA (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2, varscan2
- DEFB119 | c.61+1207G>A | Intron (SNP) | VAF 17/142 reads (12%) | catalogued as COSV100191102; called by muse, mutect2, varscan2
- FXYD6P3 | n.223G>A | RNA (SNP) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- MCM7 | c.1849-230G>A | Intron (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100385108; called by muse, mutect2, varscan2
- NPR3 | c.*3068C>T | 3'UTR (SNP) | VAF 23/154 reads (15%) | catalogued as COSV99423674; called by muse, varscan2
- SPAG8 | c.*239C>T | 3'UTR (SNP) | VAF 15/155 reads (10%) | catalogued as COSV99428141; called by muse, mutect2, varscan2
